Somatic mutation profile of tumor specimen TCGA-EJ-7788-01A (aliquot TCGA-EJ-7788-01A-11D-2114-08) from TCGA case TCGA-EJ-7788, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.7 years (19,623 days).
Specimen TCGA-EJ-7788-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 742ccd64-8b22-4a44-a281-388f72e1cf1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7788-10A (Blood Derived Normal), aliquot TCGA-EJ-7788-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e89384e7-ce7e-4f96-a34a-4f6081b10af0

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Splice Site 1, RNA 1, Intron 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.1636G>A p.V546M | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs62640041, COSV61357144; called by muse, mutect2, varscan2
- ADAM29 | c.937T>C p.C313R | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63663224; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs200730426, COSV58443069; called by muse, mutect2, varscan2
- CBLN1 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.123); catalogued as COSV54653865; called by muse, mutect2, varscan2
- CFH | c.1679A>G p.D560G | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.697); catalogued as COSV66407970; called by muse, mutect2
- CRAMP1 | c.2311A>G p.K771E | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51961812; called by muse, mutect2, varscan2
- CYP27B1 | c.803T>C p.V268A | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV56984805; called by muse, mutect2, varscan2
- DNAH1 | c.11606A>T p.Y3869F | Missense Mutation (SNP) | VAF 100/341 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as COSV56233843; called by muse, mutect2, varscan2
- FOXC2 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.262); catalogued as rs1184166552, COSV57443610; called by muse, mutect2, varscan2
- GK | c.1150G>C p.G384R (on ENST00000427190 / NM_001205019.2; = p.G378R on NM_000167.6) | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66732276; called by muse, mutect2, varscan2
- HEATR5B | c.2441C>T p.A814V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV51852248; called by muse, mutect2, varscan2
- KIR3DL1 | c.449T>C p.F150S | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs748716415; called by muse, mutect2, varscan2
- MAGEC3 | c.1045C>A p.Q349K | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV53579585, COSV68923893; called by muse, mutect2, varscan2
- MEMO1 | c.247G>T p.V83L | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV54451733; called by muse, mutect2, varscan2
- MRGPRD | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1049161913, COSV58422812; called by muse, mutect2, varscan2
- POSTN | c.1159C>A p.L387I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV65712818; called by muse, mutect2, varscan2
- PTK7 | c.429G>C p.Q143H | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.852); catalogued as rs1226249689, COSV57848347; called by muse, mutect2, varscan2
- RALBP1 | c.814C>T p.R272* | Nonsense Mutation (SNP) | VAF 9/88 reads (10%) | catalogued as rs770022126, COSV50035172; called by muse, mutect2, varscan2
- SERINC1 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 63/199 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV60101981; called by muse, mutect2, varscan2
- STK35 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55690422; called by muse, mutect2, varscan2
- TOP3B | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV64117176; called by muse, mutect2
- ZNF615 | c.255T>A p.D85E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV65032987; called by muse, mutect2, varscan2
- KCTD20 | c.516_537+1del p.X172_splice | Splice Site (DEL) | VAF 20/107 reads (19%) | called by mutect2, pindel
- MED26 | c.151del p.T51Hfs*77 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- ATP9A | c.1791G>T p.R597= | Silent (SNP) | VAF 128/444 reads (29%) | catalogued as COSV58765963; called by muse, mutect2, varscan2
- CEBPE | c.421C>T p.L141= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV52829693; called by muse, mutect2, varscan2
- CRAMP1 | c.2310G>A p.G770= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV51961786; called by muse, mutect2, varscan2
- DAPK1 | c.312C>T p.F104= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1161473971, COSV63787074; called by muse, mutect2
- DLG2 | c.1860A>G p.G620= | Silent (SNP) | VAF 52/120 reads (43%) | catalogued as COSV54640337; called by muse, mutect2, varscan2
- FCSK | c.1212G>A p.L404= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs1446384414; called by muse, mutect2
- GDPD5 | c.1482C>T p.D494= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as rs371504591; called by muse, mutect2, varscan2
- KRI1 | c.855G>A p.E285= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs769689059, COSV57264408; called by muse, mutect2, varscan2
- LPP | c.636G>T p.T212= | Silent (SNP) | VAF 41/119 reads (34%) | catalogued as COSV57085189, COSV57088827; called by muse, mutect2, varscan2
- NPHP4 | c.2109C>T p.L703= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs373182062; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- DPP6 | c.627+21049C>T | Intron (SNP) | VAF 76/201 reads (38%) | catalogued as COSV59610550; called by muse, mutect2, varscan2
- RNF217-AS1 | n.1181C>A | RNA (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
